Somatic mutation profile of tumor specimen TCGA-55-6984-01A (aliquot TCGA-55-6984-01A-11D-1945-08) from TCGA case TCGA-55-6984, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB.
Specimen TCGA-55-6984-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 09403493-a14f-46c3-8d89-4b7b5ac407b1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-6984-11A (Solid Tissue Normal), aliquot TCGA-55-6984-11A-01D-1945-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d413c741-61a3-4635-9873-ca37b12af6c4

The open-access MAF lists 23 somatic variants for this specimen: 17 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 5, Frame Shift Del 2, Splice Site 1, Nonsense Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 5/13 reads (38%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AHCY | c.739A>G p.I247V | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.255); catalogued as rs371055374; called by muse, mutect2, varscan2
- AHNAK | c.8632A>T p.I2878F | Missense Mutation (SNP) | VAF 35/186 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.059); catalogued as COSV57222241; called by muse, mutect2, varscan2
- ASXL2 | c.2062G>A p.G688R | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.745); catalogued as rs1467046228, COSV55463194; called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.926A>T p.E309V | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs201232183, COSV50052292; called by muse, mutect2, varscan2
- GTF2IRD2B | c.2611G>A p.D871N | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.272); catalogued as rs1554532512; called by mutect2, varscan2
- KAT2B | c.1060G>T p.E354* | Nonsense Mutation (SNP) | VAF 10/42 reads (24%) | catalogued as COSV55432037; called by muse, varscan2
- MYBL2 | c.1483C>T p.P495S | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.168); catalogued as rs1568874911, COSV53831962; called by muse, mutect2, varscan2
- OR2T3 | c.85G>T p.A29S | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.82); PolyPhen benign (0.009); catalogued as COSV100613001; called by muse, mutect2, varscan2
- OR8B2 | c.797C>A p.S266Y | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV66665076; called by muse, mutect2, varscan2
- OSCP1 | c.40G>A p.G14S | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52487190; called by muse, mutect2, varscan2
- POLR3C | c.341G>A p.G114D | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61937020; called by muse, mutect2
- SPEF2 | c.835G>A p.D279N | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.071); catalogued as rs375805421, COSV56795739; called by muse, mutect2, varscan2
- ZYX | c.148C>T p.P50S | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as COSV59556979; called by muse, mutect2
- ARHGAP21 | c.274_277del p.Q92Efs*33 | Frame Shift Del (DEL) | VAF 8/36 reads (22%) | called by mutect2, pindel
- ATP2B1 | c.2268_2289del p.D756Efs*18 | Frame Shift Del (DEL) | VAF 12/62 reads (19%) | called by mutect2, pindel
- EPC2 | c.308_313+3del p.X103_splice | Splice Site (DEL) | VAF 10/85 reads (12%) | called by mutect2, pindel
- CACHD1 | c.1080G>A p.A360= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as rs748358875, COSV51556954; called by muse, mutect2, varscan2
- H6PD | c.1308C>T p.L436= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as rs1321535097, COSV66231571; called by muse, mutect2, varscan2
- HMCN1 | c.12528A>T p.G4176= | Silent (SNP) | VAF 9/78 reads (12%) | catalogued as COSV54919572; called by muse, mutect2, varscan2
- MYO16 | c.1338G>A p.E446= | Silent (SNP) | VAF 7/55 reads (13%) | catalogued as COSV51806228; called by muse, mutect2, varscan2
- OR10Z1 | c.525G>A p.Q175= | Silent (SNP) | VAF 48/120 reads (40%) | catalogued as COSV63525690; called by muse, mutect2, varscan2
- AC245884.12 | n.21C>G | RNA (SNP) | VAF 10/36 reads (28%) | catalogued as rs1415445501; called by muse, mutect2, varscan2
